Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5443, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5443-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Collected:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) LARYNX, WIDEFIELD TOTAL LARYNGECTOMY:

Larynx:

INVASIVE SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED (4.0 CM), RIGHT PYRIFORM SINUS
Resection margins are free of tumor
Perineural and lymphovascular invasion are not identified
Thyroid gland with no diagnostic abnormality

Right neck dissection:

No tumor present in nine lymph nodes (0/9)

Left neck dissection:

No tumor present in two lymph nodes (0/2)

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) WIDEFIELD TOTAL LARYNGECTOMY - A total laryngectomy, right thyroid lobe lobectomy, and bi-level neck dissection with overall measurement of 12.0 x 7.0 x 6.0 cm. An ulcerated excavated lesion occupying the right pyriform sinus and extending deep into the soft tissue measuring 3.5 x 3.0 x 4.0 cm in diameter. The tumor extends to soft tissue, but does not involve cartilage or bone and does not involve the right laryngeal mucosa. The mucosal and the surgical margin of resection are grossly free of tumor.

SECTION CODE: A1-A9, section taken for frozen section; A10, normal right lobe of thyroid; A11, sliced transglottic mucosa; A12, left transglottic mucosa; A13, colloid nodule of the right thyroid; A14-A30, sequential sectioning of tumor and adjacent mucosa from superior to inferior; A31, right level 1, two lymph nodes; A32, right level 1, two lymph nodes; A33, right level 2, three lymph nodes; A34, right level 3, one lymph node; A35, A36, one lymph node (2.0 cm) bisected; A37, left level 1, one possible lymph node; A38, left level 2, two possible lymph nodes; A39, left level 3, two possible lymph nodes.

*FS/DX: MUCOSAL MARGINS, NEGATIVE FOR TUMOR. TRACHEAL MARGIN WITH FOCAL AREAS OF NECROSING MUCOSA WITH MARKED ACUTE INFLAMMATION.

CLINICAL HISTORY

None given.

SNOMED CODES

[page 2 of 2]
[Redacted]

[Redacted]

Surgical Pathology Report

[Redacted]

Collected: [Redacted]
Received: [Redacted]

Pathologist: [Redacted]
Case type: Surgical Case

[Redacted]

[Redacted]

[Redacted]

Source: NCI Genomic Data Commons file a2dcec42-b9c1-4ade-b230-480c22d47133 (TCGA-CV-5443.1B885439-1F88-4434-989D-20C4C1B89493.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).